Somatic mutation profile of tumor specimen MP2PRT-PARPEE-TMP1-A (aliquot MP2PRT-PARPEE-TMP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PARPEE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.2 years (1,520 days).
Specimen MP2PRT-PARPEE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b337eb66-021d-4b91-b957-740abc20a6e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARPEE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARPEE-NB1-A-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d906c9ed-ba8b-4c2d-8996-598c999fe704

The open-access MAF lists 23 somatic variants for this specimen: 16 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 5, 3'Flank 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC132217.2 | c.166C>T p.R56W | Missense Mutation (SNP) | VAF 47/568 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.649); catalogued as rs1304549931, COSV56097132; called by muse, mutect2
- C10orf90 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 52/636 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372468399; called by muse, mutect2
- COL4A5 | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 79/697 reads (11%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV60355924; called by muse, mutect2, varscan2
- DIP2A | c.3727G>A p.V1243I | Missense Mutation (SNP) | VAF 155/515 reads (30%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.479); catalogued as rs752929366; called by muse, mutect2, varscan2
- GPATCH2 | c.1023C>G p.F341L | Missense Mutation (SNP) | VAF 7/160 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100861377; called by muse, mutect2
- JMJD1C | c.4169C>A p.T1390K | Missense Mutation (SNP) | VAF 128/386 reads (33%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs747375729; called by muse, mutect2, varscan2
- NME6 | c.17G>A p.R6Q (on ENST00000415053; = p.R14Q on NM_005793.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/381 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.243); catalogued as rs749006710, COSV56641023; called by muse, mutect2
- RGPD4 | c.2582C>T p.T861I | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs1170242385; called by mutect2, varscan2
- TUBB4A | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 56/580 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.967); catalogued as COSV51155846; called by muse, mutect2
- ERBB4 | c.3074C>A p.P1025H | Missense Mutation (SNP) | VAF 27/395 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2
- GON4L | c.5072C>G p.A1691G | Missense Mutation (SNP) | VAF 90/318 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- IGHV1-45 | chr14:106506995 GTATCTTGC>TGAG | Missense Mutation (DEL) | VAF 83/104 reads (80%) | called by pindel, varscan2*
- LSM14A | c.842G>C p.R281T | Missense Mutation (SNP) | VAF 55/541 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.395); called by muse, mutect2
- SLFN11 | c.914G>C p.R305T | Missense Mutation (SNP) | VAF 89/210 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- TMC5 | c.2528C>T p.P843L (on ENST00000396229 / NM_001105248.1; = p.P597L on NM_024780.5) | Missense Mutation (SNP) | VAF 154/390 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- UAP1L1 | c.1179-25_1198delinsTCCCGGA p.X393_splice | Splice Site (DEL) | VAF 108/373 reads (29%) | called by pindel, varscan2*
- CBLN2 | c.78C>T p.G26= | Silent (SNP) | VAF 183/571 reads (32%) | catalogued as rs746357871, COSV99504649; called by muse, mutect2, varscan2
- CYSLTR2 | c.222C>T p.N74= | Silent (SNP) | VAF 133/300 reads (44%) | catalogued as rs376375520; called by muse, mutect2, varscan2
- IGSF21 | c.690C>A p.S230= | Silent (SNP) | VAF 202/575 reads (35%) | called by muse, mutect2, varscan2
- JMJD1C | c.4170G>A p.T1390= | Silent (SNP) | VAF 129/384 reads (34%) | catalogued as rs761026917; called by muse, mutect2, varscan2
- PCDHGA9 | c.660G>A p.P220= | Silent (SNP) | VAF 83/323 reads (26%) | called by muse, varscan2
- IGHV4-28 | chr14:106324253 ins TCAAA | 3'Flank (INS) | VAF 57/144 reads (40%) | called by mutect2, pindel, varscan2
- IGHV4-61 | chr14:106639118 ins GGT | 3'Flank (INS) | VAF 78/111 reads (70%) | called by mutect2, pindel, varscan2
